Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5327, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5327-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Lymph-Node: level 4, rt neck
2. Lymph node: level 1 lymph node Rt neck
3. Oral Cavity: Rt tongue base QS
4. Oral Cavity: left vallecula QS
5. Oral Cavity: left lateral pharynx QS
6. Oral Cavity: left lateral floor of mouth
7. Oral Cavity: Rt posterior tongue base QS
8. Oral Cavity: near total glossectomy
9. Neck: bilateral neck dissection
10. Lymph node: Rt penfacial node
11. Lymph node: Rt penfacial node
12. Surgical Waste: surgical waste

Diagnosis

1. Lymph node; level IV, right neck:
- Three lymph nodes, negative for tumor (0/3).
2. Lymph node; level I; right neck:
- One lymph node, negative for tumor (0/1).
3. Oral cavity; right tongue base:
- Skeletal muscle, negative for tumor.
4. Oral cavity; left vallecula:
- Squamous mucosa, negative for tumor.
5. Oral cavity; left lateral pharynx:
- Squamous mucosa, negative for tumor.
6. Oral cavity; left lateral floor of mouth:
- Squamous mucosa and skeletal muscle, negative for tumor.
7. Oral cavity; right posterior tongue base:
- Squamous mucosa and skeletal muscle, negative for tumor.
8. Oral cavity resection; near total glossectomy:
- Squamous cell carcinoma, moderately differentiated.
- a. Maximum tumor dimension 6.5 cm.
- b. Maximum tumor thickness 2.2 cm.

[page 2 of 4]
Surgical Pathology Consultation Report

- c. No perineural invasion present.
- d. No lymphovascular invasion present.
- e. Tumor is present at the infero-anterior margin.
- f. Tumor is close (0.1 - 0.2 cm) to left oropharynx and deep soft tissue margins.
- g. Tumor is close (0.3 - 0.4 cm) to medial tongue, deep floor of mouth and postero-lateral floor of mouth margins.

9. Bilateral neck dissection (see comment):

- Metastatic squamous cell carcinoma in five of twenty-five lymph nodes in right neck (5/25).
- i. Largest involved lymph node measures 1.0 cm.
- ii. Involved lymph nodes are in levels IB, II and III.
- iii. No extracapsular extension present.
- Metastatic squamous cell carcinoma in four of thirty lymph nodes in left neck (4/30).
- iv. Largest involved lymph node measures 1.9 cm.
- v. Involved lymph nodes are in levels IB and II.
- vi. No extracapsular extension present.
- Right and left submandibular glands with no pathologic changes.

10. Right perfacial lymph node:

- One lymph node, negative for tumor (0/1).
- Fragment of parotid tissue with no pathologic changes.

11. Right perfacial lymph node:

- One lymph node, negative for tumor (0/1).

12. Surgical waste:

- Fibroadipose tissue and skin with no pathologic changes (gross examination only).

Synoptic Data

Specimen Type:	Resection: Near total glossectomy
Tumor Site:	Tongue
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 6.5 cm Tumor thickness: 2.2 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	Carcinoma in situ
Margins:	Margin(s) involved by tumor Location(s): infero-anterior
Pathologic Staging (pTNM):	pT3: Tumor or lip or oral cavity more than 4 cm in greatest dimension pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx Number of regional lymph nodes examined: 55 Number of regional lymph nodes involved: 9 Extra-capsular extension of nodal tumor: Absent pMX: Distant metastasis cannot be assessed

Comment

All nine positive lymph nodes in the bilateral neck dissection contain micrometastases only. The size of the largest node in each neck is based on the node size and not the size of the metastasis.

[page 3 of 4]
Clinical History

oral ca

Gross Description

1. The specimen is labeled with the patient's name and "level IV, right neck". It consists of portion of fibroadipose tissue measuring 1.7 x 1.4 x 0.3 cm. Multiple lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 0.6 x 0.5 x 0.3 cm are identified. Representative sections are submitted.

1A two lymph nodes

1B one lymph node bisected

2. The specimen is labeled with the patient's name and "level I lymph node right neck". It consists one lymph node measuring 0.2 x 0.2 x 0.2 cm.

2A submitted in toto

3. The specimen is labeled with the patient's name and as "right tongue base qs". It consists of a fragment of tissue measuring 1.1 x 0.5 x 0.3 cm. The specimen is submitted in toto for frozen section.

3A frozen section control

4. The specimen is labeled with the patient's name and as "left vallecula qs". It consists of a fragment of tissue measuring 0.9 x 0.4 x 0.2 cm. The specimen is submitted in toto for frozen section.

4A frozen section control

5. The specimen is labeled with the patient's name and as "left lateral pharynx qs". It consists of a fragment of tissue measuring 1.4 x 0.3 x 0.3 cm. The specimen is submitted in toto for frozen section.

5A frozen section control

6. The specimen is labeled with the patient's name and as "left lateral floor of mouth qs". It consists of a fragment of tissue measuring 1.2 x 0.3 x 0.3 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

7. The specimen is labeled with the patient's name and as "right posterior tongue base qs". It consists of a fragment of tissue measuring 0.9 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "near total glossectomy". It consists of a large portion of left tongue measuring 5.0 cm SI x 3.5 cm ML x 8.5 AP. There is no suture orientation. There is a large endophytic tumor involving the lateral surface of the tongue. The tumor measures 4.0 cm SI x 2.2 cm ML x 6.5 cm AP. The tumor is solid and tan with a nodular/papillary like component. It appears grossly to be located at 0.2 cm from the deep lateral floor of mouth mucosal margin, 0.5 cm from the medial margin, < 0.1 cm from the deep margin, abuts the left infero-anterior margin, and 0.5 cm from the posterior margin. The remaining tongue mucosa shows a yellowish white tiny 0.2 cm nodule at the postero lateral tongue margin. Representative sections are submitted.

8A left infero anterior margin

8B deep floor of mouth mucosal margin

8C postero lateral deep floor mouth mucosal margin

8D left oropharynx mucosal margin

8E posterior tongue margin

8F medial tongue margin

8G deep soft tissue margin

8H, 8I tumor

9. The specimen is labeled with the patient's name and "bilateral neck dissection". It consists of an oriented modified bilateral neck dissection with overall dimensions of 15 x 9 x 1.5 cm. The specimen is oriented on a green towel as right and left levels I through IV. The internal jugular vein is not identified. No sternocleidomastoid is identified. The right submandibular gland measures 3.5 x 2.5 x 1.2 cm and is unremarkable. The left submandibular gland measures 3.0 x 2.0 x 1 cm and is grossly unremarkable. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.1 cm to 2 x 1 x 0.8 cm are identified in multiple levels. Representative sections are submitted.

[page 4 of 4]
9A right submandibular gland
9B, 9C right level IB multiple lymph nodes each block
9D right level IB one lymph node bisected
9E, 9F right level II multiple lymph nodes each block
9G, 9H right level II one lymph node bisected each block
9I right level III multiple lymph nodes
9J right level III two lymph nodes
9K right level IV two lymph nodes
9L left submandibular gland
9M, 9N left level IB one lymph node bisected each block
9O left level IB multiple lymph nodes
9P left level II one lymph node bisected
9Q, 9R left level II multiple lymph nodes
9S left level III multiple lymph nodes
9T left level IV multiple lymph nodes
9U level IA multiple lymph nodes

10. The specimen is labeled with the patient's name and as "right penfacial node". It consists of one lymph node measuring 0.5 x 0.4 x 0.2 cm.
10A submitted in toto

11. The specimen is labeled with the patient's name and as "right penfacial node". It consists of one lymph node measuring 0.8 x 0.7 x 0.3 cm.
11A submitted in toto

12. The specimen is labeled with the patient's name and as "surgical waste". It consists of three pieces of fibroadipose tissue and two pieces of tan skin received in 10% buffered formalin. The skin measures 2 x 1 x 0.3 cm and 4.5 x 3.5 x 0.2 cm and the largest piece of fibroadipose tissue measures 3 x 2 x 1.3 cm. No gross abnormality is noted.
No sections are submitted for histologic examination.

Quick Section Diagnosis

3. right tongue base: negative for malignancy.
4. left vallecula: negative for malignancy.
5. left lateral pharynx: negative for malignancy.
6. left lateral floor of mouth: negative for malignancy.
7. right posterior tongue base: negative for malignancy.

Source: NCI Genomic Data Commons file 22e278b7-01df-424c-a056-e88c18aa36c4 (TCGA-CQ-5327.806F62CE-271C-41E9-968B-B557486B3974.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).